Gene-level copy-number profile of tumor specimen TARGET-40-PAUYTT-01A from TARGET case TARGET-40-PAUYTT, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.3 years (6,702 days).
Specimen TARGET-40-PAUYTT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.38ad88b0-cbfd-5c85-a7ee-2508418a42bf.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAUYTT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 405 have no estimate.
https://portal.gdc.cancer.gov/files/a4575eaf-00b1-406e-9969-f93c9c6257a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 541; copy number 1: 13,415; copy number 2: 40,045; copy number 3: 4,178; copy number 4: 101; copy number 5: 17; copy number 6: 77; copy number 7: 297; copy number 8: 230; copy number 9: 650; copy number 10: 572; copy number 11: 65; copy number 12: 25; copy number 13: 3; copy number 14: 1; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,208,082–141,208,376, 1 gene: RPS16P3.
- chr3:87,323,268–87,324,723, 1 gene: KRT8P25.
- chr3:116,645,902–117,027,039, 8 genes: BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr5:165,129,307–165,153,014, 1 gene (within-gene range 0–1): AC091973.1.
- chr5:165,905,126–166,382,599, 4 genes: AC008489.1, RPL7P20, AC114321.1, AC026403.1.
- chr6:167,607–206,392, 4 genes: AL035696.2, AL035696.3, AL035696.4, AL035696.1.
- chr11:80,321,620–80,528,066, 2 genes: AP006295.1, RNU6-544P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,938 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,038,842–95,247,225, 534 genes, copy number 7–13 (within-gene range 2–13) (broad region; genes not listed).
- chr1:96,583,209–96,823,738, 5 genes, copy number 8 (within-gene range 2–8): RN7SL831P, NDUFS5P2, RPL7P9, RN7SKP270, PTBP2.
- chr6:25,061,626–33,276,511, 570 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr6:36,871,870–36,986,298, 4 genes, copy number 5 (within-gene range 3–5): C6orf89, AL122034.1, PI16, MTCH1.
- chr6:37,091,314–37,550,860, 14 genes, copy number 5–8 (within-gene range 3–8): RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1.
- chr6:38,587,323–38,715,217, 3 genes, copy number 9: AL079341.1, GLO1, AL391415.1.
- chr6:38,744,086–38,764,694, 2 genes, copy number 9: RN7SL465P, AL035555.2.
- chr6:41,026,895–49,273,794, 202 genes, copy number 9–10 (broad region; genes not listed).
- chr7:94,278,680–94,557,019, 5 genes, copy number 5 (within-gene range 2–5): AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1.
- chr17:8,120,592–21,574,517, 495 genes, copy number 6–16 (within-gene range 1–16) (broad region; genes not listed).
- chr19:27,638,483–31,466,431, 76 genes, copy number 7–11 (broad region; genes not listed).
- chr19:32,243,965–33,175,799, 27 genes, copy number 7 (within-gene range 2–7): RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88.
- chr22:32,801,705–32,863,041, 1 gene, copy number 5 (within-gene range 1–5): TIMP3.

Autosomal genes at a single copy (total copy number 1): 13,409. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
